Somatic mutation profile of tumor specimen 0DW2W7 from CCDI case PBCNFC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Craniopharyngioma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.3 years (6,301 days).
Specimen 0DW2W7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f48d2a9-541b-47e8-9928-1cb9693cf670.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DW2VM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1604a79f-134f-4eca-85a5-3d69ce24004e

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Nonsense Mutation 3, Silent 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 193/681 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: other / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.844C>T p.R282* | Nonsense Mutation (SNP) | VAF 60/1077 reads (6%) | catalogued as rs374404992, CM032793, COSV104425155, COSV66068454; called by muse, mutect2
- LRRC8B | c.2014C>G p.P672A | Missense Mutation (SNP) | VAF 29/607 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58375779; called by muse, mutect2
- ZNF316 | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 55/251 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.194); catalogued as rs922155577; called by muse, mutect2, varscan2
- ANK3 | c.128C>G p.A43G | Missense Mutation (SNP) | VAF 52/813 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 32/913 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 56/1360 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- PSCA | c.116G>A p.C39Y | Missense Mutation (SNP) | VAF 37/702 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SUFU | c.264G>A p.W88* | Nonsense Mutation (SNP) | VAF 36/585 reads (6%) | called by muse, mutect2
- SYT5 | c.1113G>A p.W371* | Nonsense Mutation (SNP) | VAF 18/268 reads (7%) | called by muse, mutect2
- PHACTR4 | c.528C>G p.S176= (on ENST00000373839 / NM_001350159.2; = p.S186= on NM_023923.4) | Silent (SNP) | VAF 20/647 reads (3%) | called by muse, mutect2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 16/290 reads (6%) | called by muse, mutect2
